Gene-level copy-number profile of tumor specimen TCGA-SI-A71P-01A from TCGA case TCGA-SI-A71P, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant peripheral nerve sheath tumor; Tissue or organ of origin: Peripheral nerves and autonomic nervous system of upper limb and shoulder; Age at diagnosis: 50.3 years (18,367 days).
Specimen TCGA-SI-A71P-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.ceb4480a-f13b-40df-a89a-2e7cfa7a4b2d.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-SI-A71P-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/9d3fd152-cd49-4225-87aa-d4f7dbf4e307

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 17; copy number 1: 16,547; copy number 2: 42,248; copy number 3: 994; copy number 4: 13; copy number 5: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-SI-A71P-01A-12D-A33D-01): tumor purity 0.32, ploidy 3.26, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 17 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr13:113,878,489–114,337,626, 17 genes (within-gene range 0–2): LINC00454, BX072579.2, LINC00452, LINC00565, C13orf46, RASA3, RASA3-IT1, CFAP97D2, AL160396.1, CDC16, MIR548AR, MIR4502, AL160396.2, UPF3A, CLCP2, CHAMP1, LINC01054.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:62,275,361–62,275,678, 1 gene, copy number 5: AC128676.1.

Autosomal genes at a single copy (total copy number 1): 14,126. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
